Somatic mutation profile of tumor specimen TCGA-RZ-AB0B-01A (aliquot TCGA-RZ-AB0B-01A-11D-A39W-08) from TCGA case TCGA-RZ-AB0B, project TCGA-UVM (Uveal Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed epithelioid and spindle cell melanoma; Tissue or organ of origin: Overlapping lesion of eye and adnexa; AJCC pathologic stage: Stage IV; Age at diagnosis: 48.0 years (17,514 days).
Specimen TCGA-RZ-AB0B-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1fe7849-e804-4e00-894b-b03b5bdf44b1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RZ-AB0B-10A (Blood Derived Normal), aliquot TCGA-RZ-AB0B-10A-01D-A39Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90042d04-8967-4573-a51a-080c0ccde552

The open-access MAF lists 13 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 10, Silent 1, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNA11 | c.626A>T p.Q209L | Missense Mutation (SNP) | VAF 27/71 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1057519742, COSV50017277, COSV50017623, COSV50017882; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ARSJ | c.1504C>A p.P502T | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV59539032; called by muse, mutect2, varscan2
- COL14A1 | c.1580C>T p.T527M | Missense Mutation (SNP) | VAF 103/126 reads (82%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as rs748226555, COSV52866169; called by muse, mutect2, varscan2
- DNAH8 | c.5453G>A p.R1818H | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758868992, COSV59480066; called by muse, mutect2
- LILRA2 | c.868G>A p.G290R | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.486); catalogued as rs368237647, COSV52194613; called by muse, mutect2, varscan2
- MTOR | c.7501A>T p.I2501F | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.764); catalogued as COSV63871874; called by muse, varscan2
- SHANK1 | c.169C>T p.L57F | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV53260380; called by muse, mutect2
- GMEB2 | c.227T>A p.L76* | Nonsense Mutation (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- LSM1 | c.345G>C p.Q115H | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- MTOR | c.7463T>G p.V2488G | Missense Mutation (SNP) | VAF 52/60 reads (87%) | SIFT tolerated (0.41); PolyPhen benign (0.021); called by muse, varscan2
- PPP4R1 | c.2425G>T p.V809L (on ENST00000400556 / NM_001042388.3; = p.V792L on NM_005134.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKCB | c.1745_1757delinsT p.K582_C586delinsI | In Frame Del (DEL) | VAF 47/114 reads (41%) | called by pindel, varscan2*
- POU4F1 | c.972G>A p.A324= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2
